Surgical pathology report (de-identified scan), TCGA case TCGA-FG-6688, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-6688-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Name:

Accession #:

Date of Procedure:

Date Received:

Submitting Physician:

Med. Rec #.

Location:

Race:

DOB/Sex:

FINAL DIAGNOSIS

A, B. LEFT PARIETAL OCCIPITAL GLIAL NEOPLASM, BIOPSY AND REMOVAL:
-- INFILTRATING GLIOMA, SEE NOTE.

Note: Histopathological features are consistent with derivation from the patient's previously biopsied anaplastic astrocytoma

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A.Touch Imprint and Microscopic: Infiltrating Glioma.

Clinical History:

Left occipital parietal glial neoplasm

Specimens Submitted As:

A:PARIETAL OCCIPITAL NEOPLASM

B:LEFT GLIAL NEOPLASM

Gross Description:

A: Received fresh for intraoperative consultation, labeled with the patient's name and hospital number , are multiple tan white segments of soft tissue measuring 0.5 x0.3 x 0.1 cm in aggregate.The specimen is submitted entirely in 2 cassette.

B: Received fresh, labeled with the patient's name and number, and "left glial neoplasm are multiple irregular, opaque white to tan, soft, cerebriform tissue fragments measuring in aggregate 3.5 x 2.3 x 1.0-cm. A portion of specimen is submitted to . The remaining tissue is submitted entirely in two cassettes.

Summary of cassettes

A1 FS

A2 remainder of specimen

Source: NCI Genomic Data Commons file 59a40427-11b5-4f21-958c-6dba83d0f9fa (TCGA-FG-6688.B889306A-615A-4C0E-8ACD-6BFBF08C8BF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).